Gene-level copy-number profile of tumor specimen ALCH-B1WG-TTP1-A from ALCHEMIST case ALCH-B1WG, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: male; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 65.6 years (23,949 days).
Specimen ALCH-B1WG-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 9244be92-e10d-49e0-ac6d-7114d10b563c.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator ALCH-B1WG-NB1-A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,737 have no estimate.
https://portal.gdc.cancer.gov/files/32aa1bb6-101b-4411-9a36-2d8ff6b7fe05

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 28; copy number 1: 1,103; copy number 2: 27,088; copy number 3: 23,970; copy number 4: 3,334; copy number 5: 2,089; copy number 6: 305; copy number 7: 160; copy number 8: 444; copy number 9: 95; copy number 10: 83; copy number 12: 21; copy number 13: 34; copy number 14: 1; copy number 16: 4; copy number 18: 6; copy number 20: 46; copy number 21: 71; copy number 29: 4.

Homozygous deletions (total copy number 0; autosomes only): 28 genes in 16 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:16,014,028–16,019,594, 1 gene (within-gene range 0–2): HSPB7.
- chr2:87,194,786–87,194,859, 1 gene (within-gene range 0–4): MIR4771-1.
- chr3:38,007,496–38,029,642, 2 genes: PLCD1, Y_RNA.
- chr4:68,509,441–68,670,652, 6 genes (within-gene range 0–2): UGT2B29P, UGT2B17, AC147055.2, AC147055.4, AC147055.3, UGT2B15.
- chr6:29,887,294–29,888,268, 1 gene (within-gene range 0–1): AL645929.1.
- chr6:29,934,101–29,934,286, 1 gene: HLA-U.
- chr7:157,614,023–157,618,765, 1 gene (within-gene range 0–2): AC005481.1.
- chr8:12,374,366–12,414,373, 4 genes (within-gene range 0–1): AC087203.1, AC087203.2, DEFB109A, AC087203.3.
- chr8:39,451,045–39,522,852, 1 gene: ADAM3A.
- chr9:39,748,514–39,810,097, 2 genes: GLIDR, BX664615.1.
- chr9:39,816,599–39,874,562, 1 gene (within-gene range 0–2): BX664615.2.
- chr15:20,890,206–20,890,606, 1 gene: AC012414.5.
- chr16:32,454,612–32,460,362, 2 genes: AC138915.3, AC138915.1.
- chr16:89,159,146–89,164,245, 1 gene: LINC00304.
- chr19:8,490,056–8,502,640, 1 gene: PRAM1.
- chr22:29,705,256–29,719,859, 2 genes: AC004882.1, AC004882.2.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 3,363 genes in 29 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:52,473–133,723, 4 genes, copy number 5–7 (within-gene range 2–7): OR4G4P, OR4G11P, OR4F5, AL627309.1.
- chr1:143,419,625–156,456,763, 595 genes, copy number 5 (within-gene range 3–7) (broad region; genes not listed).
- chr6:6,794,915–23,125,087, 220 genes, copy number 7–9 (broad region; genes not listed).
- chr6:29,907,783–29,908,645, 1 gene, copy number 9: MCCD1P1.
- chr6:37,433,219–37,482,827, 1 gene, copy number 5: CMTR1.
- chr6:71,550,958–76,447,089, 75 genes, copy number 5–13 (broad region; genes not listed).
- chr8:55,696,424–66,667,231, 162 genes, copy number 5–8 (broad region; genes not listed).
- chr8:66,667,615–66,685,564, 1 gene, copy number 6 (within-gene range 4–6): C8orf44.
- chr8:67,062,417–74,048,784, 110 genes, copy number 5–7 (within-gene range 4–7) (broad region; genes not listed).
- chr8:79,891,553–81,924,348, 60 genes, copy number 5: AC036214.4, MRPS28, AC036214.3, AC036214.2, AC009686.2, TPD52, AC009686.1, RN7SL41P, MIR5708, AC104212.3, AC034114.2, AC104212.2, AC104212.1, AC034114.1, RNU6-1213P, AC009812.1, Y_RNA, ZBTB10, AC009812.3, AC009812.4, RPSAP47, RNU7-174P, AC009812.2, RNU2-71P, SLC25A51P3, RN7SL107P, ZNF704, CKS1BP7, RNU11-6P, RN7SL308P, HMGB1P41, PAG1, AC022778.1, AC079209.2, AC079209.1, AC009902.1, UBE2HP1, AC009902.3, AC009902.2, FABP5, AC018616.1, PMP2, FABP9, FABP4, AC023644.1, FTH1P11, FABP12, IMPA1P1, NIPA2P4, RPS26P34, SLC10A5P1, IMPA1, SLC10A5, AC132219.2, ZFAND1, CHMP4C, AC132219.1, SNX16, HNRNPA1P36, LINC02235.
- chr8:98,371,228–98,942,827, 1 gene, copy number 8 (within-gene range 4–8): STK3.
- chr8:98,426,958–98,432,853, 1 gene, copy number 8 (within-gene range 4–8): KCNS2.
- chr8:98,603,253–102,893,864, 104 genes, copy number 6–8 (within-gene range 4–8) (broad region; genes not listed).
- chr8:119,711,830–132,848,807, 189 genes, copy number 6–10 (broad region; genes not listed).
- chr8:133,237,175–139,127,953, 53 genes, copy number 7–12: NDRG1, KC877373.1, AF186190.1, ST13P6, ST3GAL1, AC103706.2, AC103706.3, AC103706.1, AC090821.1, Metazoa_SRP, MTND2P7, MTCO1P49, AC133634.1, AC090821.2, AC090821.3, AC110741.1, AC110741.3, AC110741.2, AC105180.2, AC105180.1, ZFAT, AC015599.1, ZFAT-AS1, AC015599.2, AC015599.3, AC087045.1, AC087045.2, AC087045.3, AC083843.3, AC083843.2, MIR30B, MIR30D, AC083843.1, NCRNA00250, AC103764.1, RPL23AP56, LINC01591, AC040914.1, KHDRBS3, MAPRE1P1, RNU1-35P, LINC02055, RNU6-144P, ZYXP1, AC110053.1, AC046195.1, AC046195.2, AC079015.1, FAM135B, COL22A1, AC027541.1, AC100807.1, AC100807.2.
- chr8:143,039,209–145,066,685, 132 genes, copy number 5–9 (broad region; genes not listed).
- chr9:33,730,345–39,741,193, 212 genes, copy number 7–10 (broad region; genes not listed).
- chr9:60,914,407–61,453,030, 12 genes, copy number 10–12: SPATA31A5, AL590491.1, FAM74A6, AL590491.2, AL590491.3, SPATA31A7, BX005040.3, BX005040.2, FAM74A4, BX005040.1, CNTNAP3C, RN7SL462P.
- chr11:66,848,417–66,958,386, 1 gene, copy number 5 (within-gene range 3–5): PC.
- chr11:66,919,762–91,116,555, 609 genes, copy number 5 (broad region; genes not listed).
- chr12:6,155,035–22,618,868, 474 genes, copy number 5–6 (within-gene range 4–6) (broad region; genes not listed).
- chr12:24,566,964–32,993,754, 193 genes, copy number 5 (broad region; genes not listed).
- chr14:32,879,246–41,904,549, 133 genes, copy number 9–29 (broad region; genes not listed).
- chr15:20,835,372–20,866,314, 2 genes, copy number 5: POTEB2, RNU6-749P.
- chr15:20,901,441–20,901,609, 1 gene, copy number 7: ZNF519P2.
- chr16:11,555–38,321, 2 genes, copy number 5–14: DDX11L10, IL9RP3.
- chr16:32,475,051–32,478,250, 1 gene, copy number 8: ABCD1P3.
- chr16:34,120,470–34,268,649, 8 genes, copy number 6: AC136932.1, DUX4L45, PCMTD1P2, DUX4L46, DUX4L47, LINC00273, RNA5-8SP2, BCLAF1P2.
- chr21:44,200,602–44,262,216, 6 genes, copy number 6–13: AP001057.1, ICOSLG, AP001059.2, AP001059.1, DNMT3L, DNMT3L-AS1.

Autosomal genes at a single copy (total copy number 1): 531. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
